Gene-level copy-number profile of tumor specimen TCGA-AA-3664-01A from TCGA case TCGA-AA-3664, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 74.9 years (27,363 days).
Specimen TCGA-AA-3664-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.9f1f1ab9-ec22-4977-ba47-c070fe8eef64.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3664-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fdc3da4a-3b42-4e4d-8386-2788c758ddcf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 2,466; copy number 2: 46,414; copy number 3: 6,863; copy number 4: 2,311; copy number 5: 1,645; copy number 6: 91.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3664-01A-01D-0903-01): tumor purity 0.87, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,380,476–6,395,578, 1 gene: AC006112.1.
- chr18:50,795,120–53,535,903, 23 genes (within-gene range 0–1): MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 754 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:41,667,168–53,574,555, 186 genes, copy number 5–6 (broad region; genes not listed).
- chr8:121,612,116–145,066,685, 446 genes, copy number 5 (broad region; genes not listed).
- chr18:41,341,319–49,496,896, 122 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,432. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
